Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A73S, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A73S-01A (Primary Tumor).

[page 1 of 5]
RUN DATE:
RUN TIME:
BY:

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

*****AMENDED REPORT*****

This amendment is issued to correct the tumor location listed in the synoptic checklist to read:

right inferior quadrant (3-6 o'clock)
left inferior quadrant (6-9 o'clock)

This information correlates with the features described in the gross description and does not otherwise change the staging or diagnostic impression.

Dictated by:
Entered:

Amendment # 1 Electronically Signed by:

CLINICAL HISTORY:
CERVICAL CA

SPECIMEN/PROCEDURE:

1. LYMPH NODE, ILIAC - LEFT EXTERNAL
2. LYMPH NODE - LEFT OBTURATOR
3. LYMPH NODE, ILIAC - RIGHT EXTERNAL
4. LYMPH NODE - RIGHT OBTURATOR
5. SOFT TISSUES OF PELVIS - LEFT PERIMETRIA
6. UTERUS - AND CERVIX, BILATERAL TUBES/OVARIES
7. VAGINA - RIGHT LATERAL VAGINAL MARGIN

ICD-O-3
Carcinoma, adenocarcinoma 8560/3
Site Cervix NOS C53.9
JW 8/15/13

IMPRESSION:

- 1) LYMPH NODES, ILIAC, LEFT EXTERNAL, EXCISION:
. Three lymph nodes negative for malignancy (0/3).
- 2) LYMPH NODES, LEFT OBTURATOR, EXCISION:
. Metastatic carcinoma in one of six lymph nodes (1/6).
- 3) LYMPH NODES, ILIAC, RIGHT EXTERNAL, EXCISION:
. Metastatic carcinoma in one of four lymph nodes (1/4).
- 4) LYMPH NODES, RIGHT OBTURATOR, EXCISION:
. Five lymph nodes negative for malignancy (0/5).
- 5) SOFT TISSUE, PELVIS, LEFT PARAMETRIA, EXCISION:
. Fibroadipose tissue, negative for carcinoma.
- 6) UTERUS AND CERVIX, RADICAL HYSTERECTOMY:
. CERVIX:

** CONTINUED ON NEXT PAGE **

[page 2 of 5]
IMPRESSION: (continued)

- . Invasive adenosquamous carcinoma, nonkeratinizing, moderately differentiated (see tumor checklist).
- . Margins free of carcinoma.
- . **ENDOMETRIUM:**
- . Benign endometrial glands and stroma with hyalinized implantation site(s).
- . No evidence of hyperplasia or malignancy.
- . **MYOMETRIUM:**
- . Benign fibromuscular tissue.
- . Focal benign mucinous cyst.

7) VAGINA, LATERAL, RIGHT MARGIN:

- . Benign squamous epithelium and fibrovascular stroma.
- . Negative for malignancy.

UTERINE CERVIX: TRACHELECTOMY, HYSTERECTOMY, PELVIC EXENTERATION CASE SUMMARY

SPECIMEN

Cervix
Uterus corpus

PROCEDURE

Radical hysterectomy

TUMOR SIZE

Greatest dimension: 3.9 cm
Additional dimensions: 3.5 x 3.0 cm

TUMOR SITE

Left superior quadrant (12-3 o'clock)
Right inferior quadrant (6-9 o'clock)

HISTOLOGIC TYPE

Adenosquamous carcinoma, predominantly non-keratinizing squamous

HISTOLOGIC GRADE

G2: Moderately differentiated

MARGINS

Resection Margin

Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from margin: 7 mm
Specify location, if possible: Posterior vaginal

LYMPH-VASCULAR INVASION

Present

PATHOLOGIC STAGING (pTNM [FIGO])

PRIMARY TUMOR (pT)

pT1b1[IB1]: Clinically visible lesion < 4.0 cm in greatest dimension

REGIONAL LYMPH NODES (pN)

pN1: Regional lymph node metastasis

[page 3 of 5]
IMPRESSION: (continued)

Specify: Number of lymph nodes examined: 18
Number of lymph nodes involved: 2

DISTANT METASTASIS (pM)

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS

Adenocarcinoma in situ

Pathologic TNM (AJCC 7th edition): pT1b1 N1 M

Dictated by:

Entered:

COMMENT:

The bulky tumor has a squamoid appearance, but a somewhat atypical staining pattern, staining strongly for mCEA and negative for p63. The p16 staining pattern confirms the presence of adenocarcinoma in situ, and also highlights some superficial areas of conventional invasive adenocarcinoma. This tumor however is intimately associated with the squamoid tumor that invades deep to the surface areas of AIS. Only a very limited area of surface CIN III is identified. Extensive lymphovascular invasion is present. has reviewed selected slides and concurs.

Entered:

SPECIAL STAINS/PROCEDURES:

The following histochemical and IHC stains are performed with appropriate controls on blocks 6B and 6E:

p16: Strongly positive in surface atypical glandular areas, and moderate to weak staining of some portions of deep tumor
p63: Negative in tumor
mCEA: Strongly positive in tumor
CK7: Positive in tumor
Vimentin: Negative

Mucin: Positive in surface atypical glandular areas, no deep tumor staining.

Dictated by:

GROSS DESCRIPTION:

1. Received without fixative labeled "left external iliac" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, measuring 3.5 x 2.5 x 0.7 cm. The specimen is dissected for lymph nodes, 5 lymph nodes are identified ranging in size from 0.3 x 0.3 x 0.2 cm to 2 x 1.2 x 0.6 cm. All lymph nodes identified are submitted as follows:

Cassette 1A: 2 lymph nodes
Cassette 1B: One lymph node bisected
Cassette 1C: One lymph node bisected
Cassette 1D: One lymph node bisected

2. Received without fixative labeled "left obturator" and with the patient's name, is an

** CONTINUED ON NEXT PAGE **

[page 4 of 5]
GROSS DESCRIPTION: (continued)

aggregate of irregular portions of yellow-tan lobulated adipose tissue, measuring 5 x 3.5 x 1.6 cm. The specimen is dissected for lymph nodes, 6 lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.2 cm to 3.2 x 1.3 x 0.6 cm. All lymph nodes identified are submitted as follows:

Cassette 2A: 4 lymph nodes

Cassette 2B: One lymph node bisected

Cassette 2C-2D: One lymph node bisected

3. Received without fixative labeled "right external iliac" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, measuring 4.5 x 3.5 x 2 cm. The specimen is dissected for lymph nodes, 4 lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.2 cm to 2 x 1.5 x 0.7 cm. All lymph nodes identified are submitted as follows:

Cassette 3A: One lymph node

Cassette 3B: One lymph node bisected

Cassette 3C: One lymph node bisected

Cassette 3D-3E: One lymph node bisected

4. Received without fixative labeled "right obturator" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, measuring 4.5 x 1.4 x 0.5 cm. The specimen is dissected for lymph nodes, 6 lymph nodes are identified ranging in size from 0.2 x 0.1 x 0.1 cm to 3.5 x 1.5 x 0.4 cm. All lymph nodes identified are submitted as follows:

Cassette 4A: 4 lymph nodes

Cassette 4B: One lymph node bisected

Cassette 4C-4D: One lymph node serially sectioned

5. Received without fixative labeled "left parametria" and with the patient's name, the specimen consists of a 2.3 x 1.5 x 0.3 cm portion of yellow lobulated adipose tissue. The specimen is serially sectioned and submitted entirely in one cassette.

6. Received fresh labeled with the patient's name and "radical hysterectomy, bilateral salpingectomy" is a 222 g uterus, 10.4 x 5.5 x 4.2 cm with bilateral segments of round ligament. The uterine serosal surface has a smooth, purple to red-tan appearance and focally ragged around the lower uterine segment to cervix. The cervix is surrounded by a small, smooth and pink-tan vaginal cuff. There is an exophytic, cauliflower-like, white-tan mass, 3.9 x 3.5 x 3.0 cm, involving the posterior cervix and obstructing the os. The specimen is inked black and opened. The mass grossly appears to extend up to the lower posterior uterine segment. The endocervical canal, 2.5 x 2.2 cm, is pale tan, slightly hemorrhagic, and dilated with herringbone mucosa. The paracervical tissues are free of identifiable masses or lymph nodes. A portion of the tumor mass is submitted to TCGA with a freeze time of Upon sectioning the remaining uterus, the myometrium has an average thickness of 1.5 cm with no grossly identifiable fibroids in the endometrium has an average thickness of 0.4 cm.

CASSETTE SUMMARY:

CASSETTE 6A-6D: Posterior endocervical canal with mass, full thickness, divided in 4

CASSETTE 6E-6G: Posterior endocervical canal with mass, full thickness, bisected

CASSETTE 6H-6K: Serial sections of posterior endomyometrium

CASSETTE 6L-6N: Anterior endocervical canal and endomyometrium

** CONTINUED ON NEXT PAGE **

[page 5 of 5]
GROSS DESCRIPTION: (continued)

CASSETTE 6P: Left round ligament

CASSETTE 6Q: Right round ligament

7. Received without fixative labeled "right lateral vaginal margin" and with the patient's name, the specimen consists of a 4.5 x 1 excised to a depth of 0.8 cm unoriented excision of vaginal mucosa. The mucosa is pale tan, glistening, and grossly unremarkable. The resection margin is inked black and the specimen is serially sectioned to reveal predominantly white fibrous cut surfaces. The specimen is submitted entirely in four cassettes.

Dictated by:**Entered:****COPIES TO:****CPT Codes:**

MUCICARMINE-88313, IHC VIMENTIN-88342, IHC CEA-88342, LYMPH NODE, REGIONAL RESECT/88307/4, UTERUS W/WO ADNEXAE, TUMOR-88309, IHC CYTOKERATIN 7-88342, IHC P16-88342, IHC P63-88342, SOFT TISSUE BIOPSY/88305, VAGINAL BIOPSY/88305, NEG MAB CONTROL

ICD9 Codes:

180.1

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Dual/Syn. Ironous Primary Nodules		☒

Source: NCI Genomic Data Commons file 131c8ba2-dac2-418a-a4e3-b83815b6875b (TCGA-Q1-A73S.264F3D75-C462-4904-8AFB-2D18B0A59CB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).